Surgical pathology report (de-identified scan), TCGA case TCGA-86-7714, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-7714-01A (Primary Tumor).

[page 1 of 3]
Pathology Reports

Case ID		Subject ID		Gross Description	Microscopic Description
				Labeled right lower lobe. There is a 3.5 x 3 x 2.5 cm wedge of lung tissue with intact gray pleura. On cross section there is a 2.1 cm subpleural tumor with a glistening white mucoid surface. The tumor is 12 mm from the nearest stapled margin. The pleura has been inked blue. No satellite nodules are detected. The remaining lung tissue is brown and spongy.	Sections reveal an invasive adenocarcinoma with papillary, lipidic, acinar, and micropapillary subtypes. See checklist for additional details.

[page 2 of 3]
Diagnosis Details	Comments	Formatted Path Report
LUNG CARCINOMA CHECKLIST 1. Tumor Type: Adenocarcinoma, mixed subtype. 2. Tumor grade: Poorly differentiated. 3. Tumor location: Right lower lobe. 4. Tumor size: 2.1 cm. 5. Angiolymphatic invasion: Yes. 6. Bronchial margin: N/A. 7. Pleural involvement: Visceral pleura. 8. Lymph nodes: 1 positive out of 1 found (subcarinal lymph node) 9. Size of largest metastatic deposit: 0.25 cm. 10. pTNM: T2a N2 MX.	LUNG TISSUE CHECKLIST Specimen type: Wedge resection, lobectomy Tumor site: Lung Tumor size: 2.1 cm Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Visceral pleura Other tumor nodules: Not specified Lymph nodes: 1/1 positive for metastasis (Subcarinal lymph node 1/1) Lymphatic invasion: Present Venous invasion: Present Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None	

[page 3 of 3]
Laterality	Date of Procurement

Source: NCI Genomic Data Commons file fa3fa696-f4d3-4851-a109-6875cbe65dd7 (TCGA-86-7714.AE0A324F-8658-46B6-B870-A2642EEA57A8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).